TCGA case TCGA-DX-A7EQ — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Synovial-like Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0b6418fc-c775-4baa-8776-74ffcc492e9a

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 72 years; Vital status: Dead; Days to death: 897 days (2.5 years).

Diagnoses (3)
1. Synovial sarcoma, spindle cell (the primary disease): ICD-O-3 morphology code: 9041/3; ICD-10 code: C49.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 72.6 years (26,503 days); Year of diagnosis: 2006; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Lung, NOS; Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis percent: 5; Necrosis present: Yes; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 3; Tumor length measurement: 4.2; Tumor width measurement: 3.5.
2. Metastasis of diagnosis 1 (Synovial sarcoma, spindle cell), site: Lung, NOS. Age at diagnosis: 73.2 years (26,754 days); Days to diagnosis: 251 days; Prior treatment: Yes.
3. Metastasis of diagnosis 1 (Synovial sarcoma, spindle cell), site: Lung, NOS. Age at diagnosis: 74.6 years (27,245 days); Days to diagnosis: 742 days (2.0 years); Prior treatment: Yes.

Follow-up (3 entries)
- Day 251 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 251 days.
- Day 742 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 742 days (2.0 years).
- Days to follow up: 897 days (2.5 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 15.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-A7EQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 570 mg.
  Slide TCGA-DX-A7EQ-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-A7EQ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-A7EQ-11B: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Synovial Sarcoma - Monophasic; Margin status: Negative; Tumor total necrosis: <10% (focal necrosis); Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: Yes; Metastasis site: Lung.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Thigh/knee.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic depth: 3.0.
- Drug treatment 1: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 791; Days from index date to pharmaceutical treatment ended: 830; Pharmaceutical therapy drug name: Vorinostat; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 559; Days from index date to pharmaceutical treatment ended: 675; Pharmaceutical therapy drug name: Dacarbazine; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 3: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 559; Days from index date to pharmaceutical treatment ended: 675; Pharmaceutical therapy drug name: Sorafenib; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 3, Therapy types: Pharmaceutical therapy type: Targeted Molecular therapy.
- Drug treatment 4: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 451; Days from index date to pharmaceutical treatment ended: 508; Pharmaceutical therapy drug name: Cisplatin; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 5: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 403; Days from index date to pharmaceutical treatment ended: 424; Pharmaceutical therapy drug name: Ifosfamide; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 6: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 293; Days from index date to pharmaceutical treatment ended: 349; Pharmaceutical therapy drug name: Doxil; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Radiation treatment: Days from index date to radiation therapy started: 111; Days from index date to radiation therapy ended: 167; Radiation therapy type: External; Radiation total dose: 6600; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 37; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No; Treatment best response: Complete Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 897 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 897 days; disease-free interval: event (new tumor event after initially disease-free), 251 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 251 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-A7EQ-01A-11D-A386-01): tumor purity 0.92, ploidy 1.99, whole-genome doublings 0.
